Somatic mutation profile of tumor specimen C3L-01034-02 (aliquot CPT0170150006) from CPTAC case C3L-01034, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.7 years (24,745 days).
Specimen C3L-01034-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ade8f62-7af6-4694-ae50-6472a6e65a38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01034-31 (Blood Derived Normal), aliquot CPT0167220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b598d6f-9ae7-42cc-a7da-fb48f85e95e4

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 6 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, 5'UTR 4, Intron 3, Nonsense Mutation 3, In Frame Del 2, 3'UTR 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CETP | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs144460063, CM140761, COSV52361313; ClinVar: benign; called by muse, mutect2, varscan2
- DEFB118 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 74/438 reads (17%) | catalogued as rs1378169108, COSV53621156; called by muse, mutect2, varscan2
- GPR37 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 25/147 reads (17%) | catalogued as COSV100391121; called by muse, mutect2, varscan2
- OR8K1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as COSV54401854; called by muse, mutect2
- PIGT | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.151); catalogued as rs569386009; called by muse, mutect2, varscan2
- PTER | c.703A>C p.I235L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as rs149026663; called by muse, varscan2
- SLITRK5 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.154); catalogued as rs1458354834, COSV61522734; called by muse, mutect2, varscan2
- SYT17 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); catalogued as rs141380488; called by muse, mutect2, varscan2
- TP53 | c.377_379dup p.Y126dup | In Frame Ins (INS) | VAF 41/230 reads (18%) | catalogued as COSV53687174; called by mutect2, pindel, varscan2
- TTYH3 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs765964442; called by muse, varscan2
- ARAP1 | c.1391A>G p.K464R (on ENST00000393609 / NM_001040118.2; = p.K219R on NM_015242.4) | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ATP13A5 | c.1609A>C p.I537L | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- ATP6V1H | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- COL7A1 | c.5954G>A p.G1985D | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4Z1 | c.163T>A p.Y55N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, varscan2
- DCAF8L2 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ENTPD5 | c.300T>G p.G100= | Splice Region (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2
- FOXK2 | c.1047del p.K349Nfs*88 | Frame Shift Del (DEL) | VAF 36/152 reads (24%) | called by mutect2, pindel, varscan2
- KIF17 | c.1970dup p.S657Rfs*2 | Frame Shift Ins (INS) | VAF 48/442 reads (11%) | called by mutect2, pindel, varscan2
- MAMSTR | c.935A>G p.D312G (on ENST00000318083 / NM_001130915.2; = p.D209G on NM_182574.2) | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MATR3 | c.13T>G p.F5V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NRIP1 | c.1776_1781del p.N593_T594del | In Frame Del (DEL) | VAF 31/149 reads (21%) | called by mutect2, pindel, varscan2
- NTM | c.34A>T p.I12F | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- PAN2 | c.2776_2781delinsG p.L926Vfs*12 (on ENST00000425394 / NM_001127460.3; = p.L922Vfs*12 on NM_014871.5) | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by pindel, varscan2*
- PLA1A | c.1287-1del p.X429_splice | Splice Site (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel, varscan2
- PTPN3 | c.1067G>T p.R356I | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RPIA | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 96/485 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SIGLEC11 | c.1473G>C p.E491D | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- SOAT1 | c.124A>C p.I42L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R14 | c.767G>T p.R256M | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TBCK | c.2522A>G p.K841R (on ENST00000273980 / NM_001163436.4; = p.K778R on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.026); called by muse, mutect2
- THBS2 | c.2935T>C p.W979R | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM176A | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VHL | c.389_400del p.V130_T133del | In Frame Del (DEL) | VAF 37/286 reads (13%) | called by mutect2, pindel
- ZNF367 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- ZNF534 | c.1424G>T p.G475V (on ENST00000332323 / NM_001143939.3; = p.G462V on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2AK1 | c.1713A>G p.R571= | Silent (SNP) | VAF 39/454 reads (9%) | called by muse, mutect2
- GBA3 | c.882G>A p.K294= | Silent (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2
- ITGB2 | c.1245G>A p.T415= (on ENST00000302347; = p.T391= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/483 reads (17%) | catalogued as rs747895476, COSV56610283; called by muse, mutect2, varscan2
- KRTAP10-12 | c.438G>A p.P146= | Silent (SNP) | VAF 176/995 reads (18%) | catalogued as rs199697371; called by muse, mutect2, varscan2
- POTEM | c.1297C>T p.L433= | Silent (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- SOHLH1 | c.6G>A p.A2= | Silent (SNP) | VAF 55/449 reads (12%) | catalogued as rs372445466; called by muse, mutect2, varscan2
- ARRDC2 | c.-51C>A | 5'UTR (SNP) | VAF 39/276 reads (14%) | called by muse, mutect2, varscan2
- CDH22 | c.-39C>T | 5'UTR (SNP) | VAF 28/292 reads (10%) | catalogued as rs1230490282, COSV64837136; called by muse, mutect2
- CPLANE1 | c.*2845A>T | 3'UTR (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- EFHC1 | c.*61T>A | 3'UTR (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- NR0B1 | c.-22T>C | 5'UTR (SNP) | VAF 61/158 reads (39%) | called by muse, mutect2, varscan2
- NRXN1 | c.4039-30246G>C | Intron (SNP) | VAF 19/248 reads (8%) | called by muse, mutect2
- PKD2 | c.2241-16C>G | Intron (SNP) | VAF 47/287 reads (16%) | catalogued as rs146128307; called by muse, mutect2, varscan2
- SELENOH | c.123-43G>C | Intron (SNP) | VAF 62/282 reads (22%) | called by mutect2, varscan2
- SSPOP | n.10787C>A | RNA (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- TMEM82 | c.-1C>G | 5'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, varscan2
